Surgical pathology report (de-identified scan), TCGA case TCGA-09-1666, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-1666-01A (Primary Tumor).

[page 1 of 6]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

- A. Left ovary and fallopian tube, salpingo-oophorectomy: Papillary serous carcinoma, poorly-differentiated; see comment.
- B. Right ovary and fallopian tube, salpingo-oophorectomy:
--Ovary: Papillary serous carcinoma, poorly-differentiated; see comment.
--Fallopian tube: No tumor.
- C. Liver implant, excision: Metastatic poorly differentiated papillary serous carcinoma, consistent with ovarian primary; see comment.
- D. Sigmoid colon, implant, excision: Metastatic poorly differentiated papillary serous carcinoma, consistent with ovarian primary.
- E. Uterus and cervix, hysterectomy:
--Cervix: No significant pathologic abnormality.
--Endometrium: Inactive.
--Myometrium: Intramuscular benign cellular leiomyoma.
--Serosa: Metastatic poorly differentiated papillary serous carcinoma, consistent with ovarian primary.
- F. Lymph nodes, left pelvic, excision: No tumor in seven lymph nodes (0/7).
- G. Lymph nodes, left periaortic, excision: No tumor in eleven lymph nodes (0/11).
- H. Lymph nodes, right periaortic, excision: No tumor in five lymph nodes (0/5).
- I. Lymph nodes, right pelvic, excision: No tumor in ten lymph nodes (0/10).
- J. Appendix, appendectomy: No significant pathologic abnormality, no tumor.
- K. Omentum, resection: Metastatic poorly differentiated papillary serous carcinoma, consistent with ovarian primary.
- L. Liver, implant, #2, excision: Metastatic poorly differentiated papillary serous carcinoma, consistent with ovarian primary.

COMMENT:

[page 2 of 6]
Ovarian Tumor Synoptic Comment

1. Type of tumor: Papillary serous carcinoma; Bilateral.
2. Grade of tumor: III/III, Bilateral; High grade (Poorly differentiated);
Left/Points Right/Points
Architecture 3(>50% Solid) 2(>50% Papillary)
Nuclear Grade 3 3
Mitosis(Per 10HPF) 3(31/10HPF) 3(28/10HPF)
3. Location of tumor: Bilateral ovaries.
4. Diameter of tumor: Left--12.5 cm; Right--10.0 cm.
5. Appearance of surface of ovary: Multinodular, alternating solid and soft, papillary, and friable.
6. Condition of capsule: Bosselated but smooth.
7. Appearance of cut surface: Multinodular, solid and friable.
8. Color of solid areas: White-tan.
9. Necrosis: Present.
10. Lymphatic/vascular invasion: Not present.
11. Sites of metastases in pelvis: The serosa of the uterus.
12. Pelvic lymph nodes: No carcinoma is identified in seventeen lymph nodes (0/17).
13. Sites of metastases in abdomen: Liver, Sigmoid colon, and omentum.
14. Para-aortic lymph nodes: No carcinoma is identified in sixteen lymph nodes (0/16).
15. Peritoneal cytology: Ascites showing suspicious clusters of malignant cells.
Cytology accession number: [REDACTED]
16. Other significant findings: None.
17. FIGO stage: III.
18. TNM stage: at least pTb3N0MX (could be T3c, based on size of macroscopic peritoneal metastasis, part L was received in fragments)
An immunohistochemical test for estrogen and progesterone receptors was performed on block A8.
The test for estrogen receptors is positive. There is 3+ nuclear staining in 10% of tumor cells.
The test for progesterone receptors is negative. There is no nuclear staining in tumor cells.
Result of Her-2/*neu* test: This ovarian carcinoma is negative for Her-2/*neu* oncoprotein over-expression.
An immunohistochemical assay was performed on block A8 using the CB11 monoclonal antibody to Her-2/*neu* oncoprotein. The staining intensity of this carcinoma was 0 on a scale of 0-3 with focal cytoplasmic staining only (Her-2 test interpreted [REDACTED]).
Carcinomas with staining intensity scores of 0 or 1 are considered *negative* for over-expression of Her-2/*neu* oncoprotein.
Those with a staining intensity score of 2 are considered *borderline*. We and others have observed that many carcinomas with staining
- Page 2 of 5

intensity scores of 2 do not show gene amplification. All carcinomas with staining intensity scores of 2 are therefore submitted for FISH testing. The results of the FISH test are issued directly from the molecular cytogenetics laboratory. Carcinomas with staining intensity scores of 3 are considered *positive* for over-expression of Her-2/*neu* oncoprotein. Tumors in this category show an excellent correlation between the results of immunohistochemical and FISH testing, and almost always show gene amplification.

[page 3 of 6]
[REDACTED]

A: Left ovary and tube (FS)
B: Right ovary and tube (FS)
C: Liver implant
D: Sigmoid implant
E: Uterus and cervix
F: Left pelvic lymph node
G: Left periaortic lymph node
H: Right periaortic lymph node
I: Right pelvic lymph node
J: Appendix
K: Omentum
L: Liver implant #2

Intraoperative Diagnosis

FS1 (A) Left ovary, biopsy: High grade carcinoma, probably serous papillary. (Dr. [REDACTED])

FS2 (B) Right ovary, biopsy: High grade carcinoma, probably serous papillary. (Dr. [REDACTED])

Clinical History

This patient is a [REDACTED] with stage III ovarian carcinoma, who undergoes a modified radical hysterectomy, bilateral salpingo-oophorectomy, pelvic and periaortic lymph node dissection, appendectomy, omentectomy, tumor debulking, excision of implants on the liver.

Gross Description

The specimen is received in twelve parts, each labeled with the patient's name and medical record number.

Part A, additionally labeled "left ovary and tube," consists of a 250-gram, 12.5 x 9.5 x 9.0 cm ovarian mass

with no grossly identifiable normal ovarian tissue. The surface of the tumor is bosselated and contains

grossly visible multiple nodules, some of which are cysts containing yellow-tan, serous fluid. Cross

sectioning of the mass shows the majority of the tumor is composed of alternating solid and friable,

papillary-appearing, tan-white areas with multinodular cut surface. There is a 4.0 x 3.5 x 3.5 cm cyst

which was previously opened, with a papillary and hemorrhagic interior surface. The tumor grossly does

not invade the capsule. A 5.3 cm in length and 0.8 cm in diameter fallopian tube is present with

intraluminal soft, friable material and no tumor involvement on the interior wall is noted. A portion of the

tumor is submitted for frozen section as FS1, with the remnant submitted in cassette A1. Sections are

submitted as follows:

Cassette A2: Fallopian tube.

Cassettes A3-A15: Representative sections of tumor.

Part B, additionally labeled "right ovary and tube," consists of a 175 gram, 10.0 x 8.0 x 5.5 cm ovarian

[page 4 of 6]
mass with no grossly identifiable normal ovarian tissue. The surface of the tumor is bosselated and shows multinodular masses. Cross sectioning of the ovary shows a tumor with solid and soft friable, multinodular, tan-white cut surface. A 3.8 x 2.8 x 2.5 cm, serous cyst on the surface is also present, with a thin cyst wall and tan-light brown serous fluid. The tumor grossly does not invade the capsule. A 4.0 cm in length and 0.4 cm in average diameter fallopian tube is present on the surface of the tumor. The lumen of fallopian tube reveals no tumor. The fallopian tube is entirely submitted for microscopic examination. A portion of the tumor is submitted for frozen section as FS2, with the remnant submitted in cassette B1.

Page 3 of 5

Sections are submitted as follows:

Cassette B2: Fallopian tube.

Cassettes B3-B10: Sections of the tumor.

Cassettes B11-B13: Fallopian tube.

Part C, additionally labeled "1) liver implant," is received in formalin and consists of a single, unoriented, irregular, firm, friable, lobulated, tan-white soft tissue fragment, measuring 1.8 x 1.4 x 0.7 cm and

weighing 0.5 g. The specimen is serially sectioned and entirely submitted in cassettes C1 and C2.

Part D, additionally labeled "3 sigmoid implant (perm)," is received in formalin and consists of a single, unoriented, irregular, firm, nodular, tan-white soft tissue fragment with a yolk-yellow nodule and

brown-red streaks. The specimen measures 2.3 x 1.5 x 1.4 cm and weighs 2.5 g.

Representative sections are submitted in cassette D1.

Part E, received in formalin and labeled "uterus and cervix," consists of a uterus and cervix weighing 88 gm

and measuring 7.5 cm from fundus to cervical tip, 5.5 cm from cornu to cornu and 4.5 cm from anterior to

posterior. The serosal surface of the uterus is studded with multiple tumor implants, the largest

measuring 2.0 cm in greatest dimension. These implants are firm and tan. The endometrium,

myometrium and cervix are not involved. The endocervical canal measures 2.1 cm in length. The cervical

mucosa is tan and smooth. The ectocervical mucosa is gray-white and unremarkable. The endometrial

cavity measures 3.6 cm in length, with a diameter of 1.4 cm at the cornu. The endometrial mucosa is

brown. The endometrium measures < 0.1 cm. The myometrium is 1.3 cm in thickness. The myometrium

is homogeneous tan. There is a 1.0 cm whorled, tan mass in the fundus of the myometrium.

Representative sections are submitted as follows:

Cassettes E1-E2: Serosal surface with tumor implant.

[page 5 of 6]
Cassette E3: Anterior and posterior cervix.

Cassette E4: Endometrium and myometrium.

Cassette E5: Representative section of possible intramuscular leiomyoma.

Part F, additionally labeled "6) left pelvic lymph node," consists of six unoriented, irregular, brown-yellow

soft tissue fragments, measuring 7.2 x 3.5 x 1.4 cm and weighing 8.5 g in

aggregate. Lymph nodes are

identified and entirely submitted (none were bisected) in cassettes F1 through F4.

Part G, additionally labeled "7) left periaortic LN," consists of three unoriented, irregular, brown-tan soft

tissue fragments, with scant attached yellow fat, measuring 5.3 x 3.9 x 1.4 cm and weighing 5.5 g in

aggregate. Lymph nodes are identified and entirely submitted (none were bisected) in cassettes G1 through

G4.

Part H, additionally labeled "8) right periaortic LN," consists of four unoriented, irregular, firm, tan-brown

soft tissue fragments, measuring 4.0 x 2.0 x 1.0 cm and weighing 1.5 g in

aggregate. Lymph nodes are

identified and entirely submitted (only the lymph node in cassette H3 was bisected) in cassettes H1 through

H3.

Part I, additionally labeled "9) Right pelvic LN," consists of multiple unoriented, irregular, brown-tan soft

tissue fragments with moderate amounts of attached yellow fat, measuring 5.7 x 4.0 x 1.3 cm and weighing

6.5 g in aggregate. Lymph nodes are identified and entirely submitted (none were bisected) in cassettes I1

through I3.

Part J, additionally labeled "10) appendix," consists of a single, firm, unoriented, irregular, vermiform soft

tissue fragment, measuring 4.3 x 1.5 x 1.0 cm and weighing 2.5 g. The serosa is tan-brown with yellow

pockets of suppurative material. The specimen is gritty when sectioned and reveals a pinpoint-lumen,

surrounded by firm, white tissue. The specimen is entirely submitted in cassette J1-J3.

Part K, labeled "omentum," consists of an unoriented, tan-yellow, lobulated fragment of fibrofatty tissue

measuring 14.0 x 6.5 x 3.0 cm and weighing 175 gm. A tan-gray, firm nodule measuring 0.9 x 0.6 x 0.4 cm

is identified. No other nodules are noted, and the remainder of the tissue is composed of tan-yellow,

homogenous parenchyma. The nodule is bisected and entirely submitted in cassette K1.

Page 4 of 5

Part L, additionally labeled "12) implantation liver #2," consists of four unoriented, irregular, white-tan soft

tissue fragments, measuring 5.9 x 2.5 x 0.7 cm and weighing 3.0 g in aggregate. No gross apparent liver

parenchyma is identified. Representative sections are submitted in cassette L1.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics

[page 6 of 6]
[REDACTED]

[REDACTED] They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of

[REDACTED] as qualified to perform high-complexity clinical testing.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED]

Source: NCI Genomic Data Commons file db34f83d-1245-437d-ad63-8e5ba1db454d (TCGA-09-1666.2DE50DD9-B607-4A87-BAAE-468C4BF43205.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).